Gene-level copy-number profile of tumor specimen TCGA-BR-8678-01A from TCGA case TCGA-BR-8678, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 76.8 years (28,037 days).
Specimen TCGA-BR-8678-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.af1175d8-53eb-4cf4-907d-81f7699ea14d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8678-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2b2e7f07-9b8a-44b9-8b6c-a5e84e3f73f2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 339; copy number 2: 7,187; copy number 3: 17,523; copy number 4: 24,074; copy number 5: 5,767; copy number 6: 3,892; copy number 7: 28; copy number 8: 217; copy number 9: 735; copy number 12: 6; copy number 14: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8678-01A-11D-2390-01): tumor purity 0.7, ploidy 3.87, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–1,404,217, 16 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1.
- chr5:112,827,213–112,867,582, 1 gene (within-gene range 0–2): AC008575.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 769 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr6:44,058,792–44,378,957, 17 genes, copy number 9 (within-gene range 5–9): AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2.
- chr12:22,699,859–23,188,807, 1 gene, copy number 12 (within-gene range 1–12): AC084816.1.
- chr12:23,108,458–25,409,445, 30 genes, copy number 12–14: AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,441,052, 3 genes, copy number 14: AC092451.2, FAM133GP, TUBB4BP1.
- chr20:53,567,065–54,070,594, 8 genes, copy number 9 (within-gene range 6–9): ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1.

Autosomal genes at a single copy (total copy number 1): 339. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
